Surgical pathology report (de-identified scan), TCGA case TCGA-4Z-AA7R, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-4Z-AA7R-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Bladder

1- "Bladder + prostate + bilateral obturator lymph node chain"
High grade urothelial carcinoma, ulcerated, infiltrating until detrusor muscle;
Greatest dimension: 9.5 cm;
Perivesical fat: uninvolved by neoplasia, although it exhibits peritumoral sclerosis;
Angiolymphatic invasion present;
Perineural invasion present;
Right ureter segment: compromised by neoplasia;
Left ureter segment: compromised by neoplasia;
Prostate: compromised by neoplasia;
Seminal vesicles: uninvolved by neoplasia;
Vas deferens: uninvolved by neoplasia;
Right and left ureteral margins: uninvolved by neoplasia;
Right obturator lymph node chain: uninvolved by neoplasia (0/5)
Left obturator lymph node chain: uninvolved by neoplasia (0/2)

2- Uretral stump
Uninvolved by neoplasia

3- Left obturator lymph nodes
Uninvolved by neoplasia (0/4)

4- Right obturator lymph nodes
Uninvolved by neoplasia (0/3)

C&E ICD-O-3
Carcinoma, urothelial
papillary 8130/3
path
Carcinoma, urothelial NOS
8120/3
C&E
Site Bladder trigone 6620
path
Bladder NOS 6679
JW 3/18/14

Source: NCI Genomic Data Commons file 5edb1763-b80c-47c6-b7dc-03e5a10428f5 (TCGA-4Z-AA7R.0E7DC845-C56F-4179-9972-B1F51F00937D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).